Gene-level copy-number profile of tumor specimen TCGA-AR-A24L-01A from TCGA case TCGA-AR-A24L, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 26.6 years (9,706 days).
Specimen TCGA-AR-A24L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.0d02b005-05e4-4287-b451-40a4424d1a54.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A24L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1e6a41da-5cf6-4050-988f-fd1e6cbcfeae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 14,798; copy number 2: 34,996; copy number 3: 7,062; copy number 4: 2,763; copy number 5: 166; copy number 6: 9; copy number 7: 11; copy number 8: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A24L-01A-11D-A166-01): tumor purity 0.59, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 190 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:44,495,099–44,716,486, 3 genes, copy number 8: LINC02224, AC093292.1, RN7SL383P.
- chr5:44,752,949–44,765,744, 1 gene, copy number 8: AC093297.1.
- chr10:42,149,310–47,730,436, 166 genes, copy number 5 (broad region; genes not listed).
- chr10:59,650,761–59,960,913, 4 genes, copy number 6 (within-gene range 1–6): SLC16A9, MRLN, CCDC6, LINC01553.
- chr10:60,050,668–60,081,854, 2 genes, copy number 6: AL592430.1, Y_RNA.
- chr10:74,744,386–75,182,123, 11 genes, copy number 7: FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42.
- chr13:97,675,011–97,902,288, 3 genes, copy number 6: AL359502.1, AL359502.2, RPL7AP61.

Autosomal genes at a single copy (total copy number 1): 14,170. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
